Somatic mutation profile of tumor specimen 0DAOS7 from CCDI case PBBKFX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Oligoastrocytoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 10.4 years (3,792 days).
Specimen 0DAOS7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79f8c592-7fd8-4cc9-ae11-827b70e1b3e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAOS8 (Solid Tissue; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e787a320-6883-4993-b67c-47b7e2b05630

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL645922.1 | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484981377; called by muse, mutect2
- GTF3C5 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs894337186; called by muse, mutect2
- NPIPA5 | c.893T>C p.L298P | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs199607565; called by muse, varscan2
- SCN7A | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 363/472 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867820941, COSV69272216; called by muse, mutect2, varscan2
- TTC1 | c.836C>G p.S279W | Missense Mutation (SNP) | VAF 159/646 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370929511; called by muse, mutect2, varscan2
- CHRDL1 | c.604C>G p.R202G (on ENST00000372045; = p.R208G on NM_145234.4) | Missense Mutation (SNP) | VAF 146/435 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ESPNL | c.2771C>T p.A924V | Missense Mutation (SNP) | VAF 26/946 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.145); called by muse, mutect2
- HNRNPCL3 | c.610dup p.I204Nfs*2 | Frame Shift Ins (INS) | VAF 65/514 reads (13%) | called by mutect2, pindel, varscan2
- L3MBTL4 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 128/520 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- YWHAH | c.178T>A p.W60R | Missense Mutation (SNP) | VAF 117/535 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF27 | c.762G>A p.T254= | Silent (SNP) | VAF 173/473 reads (37%) | catalogued as rs748682659; called by muse, mutect2, varscan2
- NYX | c.630G>A p.S210= | Silent (SNP) | VAF 342/991 reads (35%) | called by muse, mutect2, varscan2
- CPSF4 | c.497+37C>T | Intron (SNP) | VAF 83/272 reads (31%) | called by muse, mutect2, varscan2
